Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A10T, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A10T-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

Collection Date :

Diagnosis:

A: Gallbladder, removal

- No significant pathologic abnormality.

B: Liver, segment II, excisional biopsy

- Well-differentiated **hepatocellular carcinoma** (1.8 cm), margins clear.

C: Right adrenal gland, removal

- No significant pathologic abnormality.

D: Liver, partial resection

- **Well-differentiated hepatocellular carcinoma** (10.5 cm in greatest dimension), medial margin focally involved.

- No lymphovascular space invasion identified.

- Minimal/mild steatosis and nonspecific portal hepatitis.

- No cirrhosis identified.

Comment:

None

Clinical History:

The patient undergoes a liver resection.

Gross Description:

Received are four appropriately containers.

Container A is additionally labeled "gallbladder."

Previously opened: yes

Measurements: 10.0 x 3.0 x 1.0 cm

External surface: dark green and smooth

Wall thickness: 0.2 cm

Mucosa: dark green and velvety

Stones present: absent

Other comments: none

Block #: A1, representative sections

Container B is additionally labeled "segment II, excisional biopsy." The specimen consists of a yellow/tan ovoid rubbery liver tissue fragment measuring 2.2 x 1.7 x 1.6 cm. A 1.0 x 1.0 cm white area is noted on the only smooth surface. Serial sectioning reveals a well circumscribed white/pink soft nodule measuring 1.8 x 1.5 x 1.0 cm. The irregular margins are inked black and the specimen is serially sectioned. (Blocks B1-B4

Container C is additionally labeled "right adrenal." The specimen consists of an adrenal gland with surrounding adipose tissue all together measuring 4.5 x 3.8 x 1.3 cm. Serial sectioning reveals a yellow/orange adrenal gland measuring 4.0 x 2.0 x 0.6 cm. (Blocks C1-C6,

Container D is additionally labeled "liver, suture medial margin." The specimen consists of a segment of liver measuring 21.0 x 14.0 x 11.0 cm and weighing 1200 grams. The external surface is tan, wrinkled with a bosselated appearance and some slightly pale areas noted. Serial sectioning reveals one white well

100-0-3

carcinoma, hepatocellular, NOS

8/7/03

Site: liver C22.0

fw
7/5/11

HPA Discrepancy		☒

[page 2 of 2]
circumscribed nodule measuring 10.5 x 10.0 x 8.5 cm. The cut surface of the nodule is yellow/red, consistent with necrosis and hemorrhage. The nodule appears friable and appears to extend to or very close to the medial margin. The remaining cut surface is homogeneous brown with dilated vessels. A suture is noted indicating medial and the entire margin is inked black. (Blocks D1-D9, representative sections)

D1-D3 - tumor and closest margin

D4,D5 - representative section of tumor

D6,D7 - tumor and capsule

D8,D9 - representative section of uninvolved liver

D10 - tumor and closest margin

Light Microscopy:

Light microscopic examination is performed.

Sections of the tumor reveal large cells with abundant pink cytoplasm. A moderate degree of cytologic atypia is observed. The tumor cells are arranged in trabeculae, many of which are greater than three cell layers. Focal necrosis is observed, and occasional mitotic figures are seen. Lymphovascular space invasion is not identified. The adjacent liver does not show cirrhosis. There is minimal steatosis and a patchy, mild, chronic inflammatory infiltrate in some portal areas.

Signature:

I have personally conducted the evaluation of the above specimens and have rendered the above diagnosis(es).

Source: NCI Genomic Data Commons file 3b3afa10-7296-4662-b588-79a90cc99598 (TCGA-BC-A10T.D8103C33-F303-4D97-81AF-CC3D06E79285.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).